Gene-level copy-number profile of tumor specimen TCGA-12-5299-01A from TCGA case TCGA-12-5299, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 56.0 years (20,463 days).
Specimen TCGA-12-5299-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.1446e12a-d1e1-45bb-b175-168e0a3dc3be.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-5299-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 359 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/38c6f3ff-8b82-4620-a219-edaaf0314f03

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 592; copy number 1: 3,997; copy number 2: 49,875; copy number 3: 2,447; copy number 4: 909; copy number 5: 2,426; copy number 27: 16; copy number 30: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-12-5299-01A-02D-1479-01): tumor purity 0.9, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 72 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:20,341,669–20,622,499, 1 gene (within-gene range 0–2): MLLT3.
- chr9:20,502,265–23,438,700, 67 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,444 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:3,301,252–4,269,000, 1 gene, copy number 5 (within-gene range 4–5): SDK1.
- chr7:3,642,815–17,346,152, 202 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:17,679,549–23,014,130, 66 genes, copy number 5 (broad region; genes not listed).
- chr7:23,710,203–30,179,014, 146 genes, copy number 5 (broad region; genes not listed).
- chr7:30,580,533–47,948,466, 313 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:48,846,426–70,838,013, 436 genes, copy number 5–30 (broad region; genes not listed).
- chr7:78,017,055–79,453,667, 1 gene, copy number 5 (within-gene range 4–5): MAGI2.
- chr7:78,486,530–91,210,590, 116 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:91,311,368–91,515,427, 1 gene, copy number 5 (within-gene range 4–5): AC079760.2.
- chr7:91,380,778–108,130,361, 417 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:109,322,320–119,907,397, 120 genes, copy number 5 (broad region; genes not listed).
- chr7:120,746,738–126,424,185, 72 genes, copy number 5 (broad region; genes not listed).
- chr7:127,476,883–133,082,932, 156 genes, copy number 5 (broad region; genes not listed).
- chr7:134,744,252–139,109,720, 73 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:139,777,051–150,398,630, 323 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:150,379,854–150,383,885, 1 gene, copy number 5: ZNF775-AS1.

Autosomal genes at a single copy (total copy number 1): 3,990. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
